Somatic mutation profile of tumor specimen TARGET-40-0A4I4E-01A (aliquot TARGET-40-0A4I4E-01A-01D) from TARGET case TARGET-40-0A4I4E, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.4 years (5,978 days).
Specimen TARGET-40-0A4I4E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca21b1f3-e527-4d40-baaf-4fa1e7d28978.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I4E-10A (Blood Derived Normal), aliquot TARGET-40-0A4I4E-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a1b5319-8b32-4f26-9630-0811f70b68ae

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, RNA 2, Silent 2, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP1A3 | c.637G>A p.G213S (on ENST00000545399 / NM_001256214.2; = p.G200S on NM_152296.5) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs1555865238; called by muse, mutect2, varscan2
- LIM2 | c.180C>G p.Y60* (on ENST00000596399 / NM_001161748.2; = p.Y102* on NM_030657.4) | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1308991717; called by muse, mutect2, varscan2
- NDOR1 | c.1723A>G p.I575V (on ENST00000371521 / NM_001144026.3; = p.I559V on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs755896139; called by muse, mutect2, varscan2
- SAMSN1 | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs1298149045; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200626474; called by muse, mutect2, varscan2
- WIPI2 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56586992; called by muse, mutect2, varscan2
- ANKRD7 | c.713-5T>C | Splice Region (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- OOSP2 | c.208A>T p.I70L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RGPD8 | c.2716T>C p.F906L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF20 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 84/615 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF20 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 105/571 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NBPF4 | c.1869C>T p.S623= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs2582071; called by muse, mutect2, varscan2
- RXFP1 | c.1782C>A p.I594= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- FAM90A20P | n.1348C>T | RNA (SNP) | VAF 10/80 reads (13%) | catalogued as rs1194340432; called by muse, mutect2
- FMNL1 | c.3211+69G>A | Intron (SNP) | VAF 30/83 reads (36%) | catalogued as rs769431859, COSV58956676; called by muse, mutect2, varscan2
- GUSBP1 | n.180-19252C>T | Intron (SNP) | VAF 12/215 reads (6%) | catalogued as rs1473703966; called by muse, mutect2
- IQCF6 | c.*3C>T | 3'UTR (SNP) | VAF 27/38 reads (71%) | catalogued as rs757074936; called by muse, varscan2
- MGST2 | c.229+3220G>T | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- PCSK4 | c.516+11G>A | Intron (SNP) | VAF 33/89 reads (37%) | catalogued as rs754026893; called by muse, mutect2, varscan2
- PRAMEF30P | n.514A>G | RNA (SNP) | VAF 10/170 reads (6%) | catalogued as rs867058110; called by muse, mutect2
